Somatic mutation profile of tumor specimen MMRF_2679_1_BM_CD138pos (aliquot MMRF_2679_1_BM_CD138pos_T1_KHS5U_L14405) from MMRF case MMRF_2679, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.2 years (17,256 days).
Specimen MMRF_2679_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1729bcec-d86b-438c-be01-727095d531e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2679_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2679_1_PB_WBC_C2_KHS5U_L14406; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/668d77c7-fb9d-4c42-bc3a-69feddf6a00e

The open-access MAF lists 103 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 28, Silent 10, Intron 8, 5'Flank 5, Nonsense Mutation 4, RNA 4, In Frame Del 3, 5'UTR 3, Frame Shift Del 2, 3'Flank 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.448C>A p.L150I | Missense Mutation (SNP) | VAF 57/357 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV59875349; called by muse, mutect2, varscan2
- ATP9B | c.3361G>A p.V1121M | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as rs778250195, COSV104410240; called by muse, mutect2, varscan2
- BRINP3 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs200210126; called by muse, mutect2, varscan2
- CACNA1B | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760821629; called by muse, mutect2, varscan2
- CDH22 | c.2140_2151del p.S714_G717del | In Frame Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs755326195; called by mutect2, varscan2
- DNAJC2 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV50789564, COSV50791643; called by muse, mutect2, varscan2
- DUOXA2 | c.227G>A p.W76* | Nonsense Mutation (SNP) | VAF 27/192 reads (14%) | catalogued as rs755647805; called by muse, mutect2, varscan2
- FREM3 | c.5644C>T p.P1882S | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as rs562316083; called by muse, mutect2, varscan2
- LNX2 | c.1115G>T p.G372V | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763700804; called by muse, mutect2, varscan2
- MGAT4C | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as COSV59837852; called by muse, mutect2, varscan2
- NOL4 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 62/333 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs757148536, COSV52338009; called by muse, mutect2, varscan2
- P2RY1 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 54/301 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.701); catalogued as rs992262820; called by muse, mutect2, varscan2
- RASA2 | c.142A>G p.K48E | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53940796; called by muse, mutect2, varscan2
- RFX4 | c.251T>G p.M84R | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.558); catalogued as COSV100774852; called by muse, mutect2, varscan2
- SCN11A | c.2323G>T p.E775* | Nonsense Mutation (SNP) | VAF 51/124 reads (41%) | catalogued as rs773777175; called by muse, mutect2, varscan2
- TRIML2 | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.17); catalogued as COSV100456279; called by muse, mutect2, varscan2
- TTN | c.24653G>A p.G8218E (on ENST00000591111; = p.G7291E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/183 reads (15%) | PolyPhen probably damaging (0.994); catalogued as COSV60235871; called by muse, mutect2, varscan2
- WDR53 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 144/316 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761288218; called by muse, mutect2, varscan2
- ZNF585A | c.450A>T p.K150N (on ENST00000292841 / NM_001288800.2; = p.K95N on NM_152655.3) | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV99493755; called by muse, mutect2, varscan2
- AEBP2 | c.281_295dup p.G94_D98dup | In Frame Ins (INS) | VAF 30/80 reads (38%) | called by mutect2, varscan2
- ANXA5 | c.579G>C p.K193N | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- ATP11B | c.2135del p.T712Kfs*5 | Frame Shift Del (DEL) | VAF 28/214 reads (13%) | called by mutect2, pindel, varscan2
- CEP95 | c.1315A>T p.M439L | Missense Mutation (SNP) | VAF 72/178 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP74 | c.2263C>G p.P755A | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CHI3L1 | c.644C>A p.T215N | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- HMCN2 | c.9251C>T p.A3084V | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IGHV2-70 | c.212_217delinsGCAATC p.L71_D73delinsRNH | Missense Mutation (ONP) | VAF 7/31 reads (23%) | called by muse*, pindel
- IGLV3-10 | c.340A>C p.N114H | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- KBTBD6 | c.1365dup p.C456Mfs*5 | Frame Shift Ins (INS) | VAF 27/44 reads (61%) | called by mutect2, pindel, varscan2
- LCE3B | c.53C>A p.S18* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- MYH2 | c.4775T>A p.L1592Q | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- OGT | c.551T>A p.I184N | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OGT | c.621T>G p.I207M | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, varscan2
- POLQ | c.2591T>C p.V864A | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- RANBP2 | c.8137_8139del p.V2713del | In Frame Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- RBP1 | c.263G>C p.S88T (on ENST00000619087 / NM_001365940.2; = p.S150T on NM_002899.5) | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SF3A2 | c.257_265del p.A86_K88del | In Frame Del (DEL) | VAF 22/65 reads (34%) | called by mutect2, pindel, varscan2
- SLF1 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPAG16 | c.1003del p.L335Ffs*10 | Frame Shift Del (DEL) | VAF 37/89 reads (42%) | called by mutect2, pindel, varscan2
- TACC2 | c.5654A>T p.H1885L (on ENST00000334433; = p.H76L on NM_206861.3) | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- TBRG1 | c.191A>G p.E64G | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- TRAF3 | c.830T>A p.L277* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- TSPAN8 | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AL603832.3 | c.471T>G p.T157= | Silent (SNP) | VAF 15/112 reads (13%) | called by muse, mutect2, varscan2
- B3GAT2 | c.165C>T p.R55= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as rs763443623; called by muse, mutect2
- CASKIN1 | c.1599C>T p.S533= | Silent (SNP) | VAF 46/109 reads (42%) | called by muse, varscan2
- GALNT18 | c.1347C>A p.T449= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV99924625; called by muse, mutect2, varscan2
- KHDC3L | c.537C>T p.T179= | Silent (SNP) | VAF 38/255 reads (15%) | catalogued as rs774772638; called by muse, mutect2, varscan2
- KLC4 | c.495G>A p.E165= | Silent (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- NUP160 | c.1692C>T p.Y564= | Silent (SNP) | VAF 44/118 reads (37%) | called by muse, mutect2, varscan2
- PLIN5 | c.1170C>T p.P390= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs377737347, COSV101113472; called by muse, mutect2, varscan2
- RELN | c.90C>T p.Y30= | Silent (SNP) | VAF 27/111 reads (24%) | catalogued as rs760806926; called by muse, mutect2, varscan2
- TACC2 | c.5919C>G p.P1973= (on ENST00000334433; = p.P51= on NM_006997.4) | Silent (SNP) | VAF 102/222 reads (46%) | called by muse, mutect2, varscan2
- AK4 | c.*5884A>G | 3'UTR (SNP) | VAF 37/82 reads (45%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021245 G>C | 5'Flank (SNP) | VAF 74/161 reads (46%) | catalogued as COSV55851570; called by muse, varscan2
- BCL7A | chr12:122021524 G>C | 5'Flank (SNP) | VAF 96/257 reads (37%) | catalogued as COSV55848044; called by muse, mutect2, varscan2
- BEND4 | c.*374G>A | 3'UTR (SNP) | VAF 32/90 reads (36%) | called by muse, mutect2, varscan2
- BTBD7 | c.-228C>T | 5'UTR (SNP) | VAF 3/22 reads (14%) | catalogued as rs1282790719; called by muse, mutect2
- C1QTNF9 | c.*621C>T | 3'UTR (SNP) | VAF 5/59 reads (8%) | catalogued as rs866142651; called by muse, mutect2
- CDC23 | c.*355G>C | 3'UTR (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- CNOT6L | c.*6373C>T | 3'UTR (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2, varscan2
- DCHS2 | n.6127-69C>A | Intron (SNP) | VAF 13/42 reads (31%) | called by muse, varscan2
- DDHD1 | c.*196C>T | 3'UTR (SNP) | VAF 34/41 reads (83%) | called by muse, mutect2, varscan2
- DDX3X | chrX:41334033 C>T | 5'Flank (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- EGFL6 | c.*218T>G | 3'UTR (SNP) | VAF 59/71 reads (83%) | called by muse, mutect2, varscan2
- EIF4A2 | c.209-129G>A | Intron (SNP) | VAF 71/310 reads (23%) | called by muse, mutect2, varscan2
- FBXL14 | c.*410G>C | 3'UTR (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- FOXN1 | c.*531G>A | 3'UTR (SNP) | VAF 55/243 reads (23%) | catalogued as rs752505969; called by muse, mutect2, varscan2
- HIVEP2 | c.*799C>T | 3'UTR (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- HNRNPUL2 | c.-124C>T | 5'UTR (SNP) | VAF 20/136 reads (15%) | catalogued as rs1248101362; called by muse, mutect2, varscan2
- HSD17B6 | c.*221G>A | 3'UTR (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2, varscan2
- IQCE | c.*2709G>A | 3'UTR (SNP) | VAF 37/106 reads (35%) | catalogued as rs1367773883; called by muse, mutect2, varscan2
- KCNJ5 | chr11:128918075 C>T | 3'Flank (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- KCNMB4 | c.*2145G>T | 3'UTR (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- KIAA1958 | c.*1790A>G | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- KLK1 | chr19:50818206 T>A | 3'Flank (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- LDHAL6A | c.-95C>T | 5'UTR (SNP) | VAF 12/114 reads (11%) | catalogued as rs1411501439, COSV99773286; called by muse, mutect2, varscan2
- MACO1 | c.*261C>T | 3'UTR (SNP) | VAF 55/125 reads (44%) | catalogued as rs1168784093; called by muse, mutect2, varscan2
- MCHR2 | c.*732T>A | 3'UTR (SNP) | VAF 6/56 reads (11%) | called by mutect2, varscan2
- MLIP | c.1114-13975T>G | Intron (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- MON1B | c.476-32G>T | Intron (SNP) | VAF 72/225 reads (32%) | called by muse, mutect2, varscan2
- NME2P1 | n.238A>C | RNA (SNP) | VAF 33/169 reads (20%) | called by muse, mutect2, varscan2
- OR7E5P | n.667C>T | RNA (SNP) | VAF 50/115 reads (43%) | called by muse, mutect2, varscan2
- ORC2 | c.*1372A>T | 3'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2
- PDE4DIP | c.2815+1387T>A | Intron (SNP) | VAF 22/143 reads (15%) | called by muse, mutect2, varscan2
- PGK2 | c.*194C>T | 3'UTR (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- PLA2G4D | c.*672G>A | 3'UTR (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
- PMP2 | c.*2973C>T | 3'UTR (SNP) | VAF 12/76 reads (16%) | catalogued as rs867630182; called by muse, mutect2, varscan2
- PRAME | chr22:22563705 C>A | 5'Flank (SNP) | VAF 71/174 reads (41%) | called by muse, mutect2, varscan2
- RASSF4 | c.*1178G>C | 3'UTR (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- RFC2 | c.*433G>A | 3'UTR (SNP) | VAF 18/121 reads (15%) | called by muse, mutect2, varscan2
- RRM2B | c.*904G>A | 3'UTR (SNP) | VAF 63/108 reads (58%) | called by muse, mutect2, varscan2
- SEC16B | c.788-36C>T | Intron (SNP) | VAF 46/130 reads (35%) | catalogued as rs766849258; called by muse, mutect2, varscan2
- SEL1L3 | chr4:25863651 A>T | 5'Flank (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- SEPHS1P1 | n.226C>T | RNA (SNP) | VAF 102/267 reads (38%) | catalogued as rs377331757; called by muse, mutect2, varscan2
- SFRP1 | c.*2970C>G | 3'UTR (SNP) | VAF 64/141 reads (45%) | called by muse, mutect2, varscan2
- SRRM2 | c.8021+453A>G | Intron (SNP) | VAF 28/170 reads (16%) | called by muse, mutect2, varscan2
- STAG3L4 | n.769A>G | RNA (SNP) | VAF 74/461 reads (16%) | called by muse, mutect2, varscan2
- TKFC | c.*1609G>C | 3'UTR (SNP) | VAF 46/326 reads (14%) | called by muse, mutect2, varscan2
- VPS13A | c.*1820G>C | 3'UTR (SNP) | VAF 37/200 reads (19%) | called by muse, mutect2, varscan2
- VWA1 | c.*118G>A | 3'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- WNT7A | c.*108G>A | 3'UTR (SNP) | VAF 35/200 reads (18%) | called by muse, mutect2, varscan2
- ZNF615 | c.238+29G>A | Intron (SNP) | VAF 18/108 reads (17%) | catalogued as rs377706028; called by muse, mutect2, varscan2
